Somatic mutation profile of tumor specimen MP2PRT-PAPYZH-TMP1-A (aliquot MP2PRT-PAPYZH-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPYZH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,106 days).
Specimen MP2PRT-PAPYZH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0478f79-aa54-4e5f-a230-a85f5247d138.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPYZH-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPYZH-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abfca1c3-55f1-4879-b2ee-a88224505cfb

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STARD9 | c.12212G>A p.R4071H | Missense Mutation (SNP) | VAF 21/486 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.616); catalogued as rs1326059731; called by muse, mutect2
- GART | c.2236A>G p.T746A | Missense Mutation (SNP) | VAF 20/655 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- IGHV3-43 | chr14:106470260 GTGTA>TCCT | Missense Mutation (DEL) | VAF 15/91 reads (16%) | called by pindel, varscan2*
- IGHV4-39 | chr14:106421702 CACTGTGTGTCTCGCACAGTAA>T | Missense Mutation (DEL) | VAF 24/158 reads (15%) | called by pindel, varscan2*
- QRFPR | c.119T>C p.L40P | Missense Mutation (SNP) | VAF 28/606 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CRYBG3 | c.6654G>A p.S2218= | Silent (SNP) | VAF 24/273 reads (9%) | catalogued as rs753867444, COSV99477162; called by muse, mutect2, varscan2
- PCDHA12 | c.1281G>A p.A427= | Silent (SNP) | VAF 40/615 reads (7%) | catalogued as COSV56476489; called by muse, mutect2
- SLC23A1 | c.1377C>T p.F459= | Silent (SNP) | VAF 15/392 reads (4%) | catalogued as COSV62297640; called by muse, mutect2
